Somatic mutation profile of tumor specimen TCGA-36-2537-01A (aliquot TCGA-36-2537-01A-01D-1526-09) from TCGA case TCGA-36-2537, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 40.0 years (14,595 days).
Specimen TCGA-36-2537-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 825814d4-53f9-4e26-b37b-ec2606dac7c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-36-2537-10A (Blood Derived Normal), aliquot TCGA-36-2537-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea389b9f-4940-4daf-9704-b048dd8dae67

The open-access MAF lists 48 somatic variants for this specimen: 33 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 14, In Frame Del 2, Frame Shift Del 2, Splice Site 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD3 | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as COSV59866474; called by muse, mutect2, varscan2
- ADGRG5 | c.740C>G p.P247R | Missense Mutation (SNP) | VAF 87/253 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61083535; called by muse, mutect2, varscan2
- CAPN3 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 152/507 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV58822708; called by muse, mutect2, varscan2
- CEACAM5 | c.1383G>T p.E461D | Missense Mutation (SNP) | VAF 220/610 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.084); catalogued as COSV55752496; called by mutect2, varscan2
- CFAP44 | c.746A>G p.N249S | Missense Mutation (SNP) | VAF 121/426 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55612056; called by muse, mutect2, varscan2
- DCHS1 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 75/111 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as rs147257039; called by muse, mutect2, varscan2
- DLC1 | c.2572G>A p.D858N (on ENST00000276297 / NM_001348081.2; = p.D421N on NM_006094.5) | Missense Mutation (SNP) | VAF 87/153 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.421); catalogued as COSV52307279; called by muse, mutect2, varscan2
- EFTUD2 | c.2446G>T p.V816F | Missense Mutation (SNP) | VAF 81/147 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV53655730; called by muse, mutect2, varscan2
- GABRA1 | c.536C>G p.A179G | Missense Mutation (SNP) | VAF 75/156 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV50106377; called by muse, mutect2, varscan2
- LTA | c.285C>A p.S95R | Missense Mutation (SNP) | VAF 144/394 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as rs1319611508, COSV69304788; called by muse, mutect2, varscan2
- MAP3K19 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 81/181 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV59639347; called by muse, mutect2, varscan2
- MDH2 | c.315G>C p.K105N | Missense Mutation (SNP) | VAF 187/853 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59884401; called by muse, mutect2, varscan2
- NEDD4 | c.3290A>G p.D1097G (on ENST00000508342 / NM_001284338.1; = p.D678G on NM_006154.4) | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767083781, COSV59062466; called by muse, mutect2, varscan2
- NFE2L3 | c.752G>C p.R251T | Missense Mutation (SNP) | VAF 93/353 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs775334870, COSV99283554; called by muse, mutect2
- NINL | c.3004G>A p.E1002K | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs779687148, COSV54001337; called by muse, mutect2, varscan2
- NLRX1 | c.537G>T p.M179I | Missense Mutation (SNP) | VAF 80/231 reads (35%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.519); catalogued as COSV99423941; called by muse, mutect2, varscan2
- NLRX1 | c.538G>T p.V180F | Missense Mutation (SNP) | VAF 79/231 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99423944; called by muse, mutect2, varscan2
- NRAP | c.5153A>T p.E1718V (on ENST00000359988 / NM_001322945.2; = p.E1683V on NM_006175.4) | Missense Mutation (SNP) | VAF 197/603 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV63491022; called by muse, mutect2, varscan2
- PIK3R4 | c.3927A>C p.K1309N | Missense Mutation (SNP) | VAF 75/248 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV62026777; called by muse, mutect2, varscan2
- PLCB4 | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 144/410 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs1200045846, COSV53803755; called by muse, mutect2, varscan2
- RPAP1 | c.3227T>G p.L1076R | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100427003; called by muse, mutect2
- SLC45A4 | c.440T>C p.L147P (on ENST00000517878 / NM_001286646.2; = p.L96P on NM_001080431.2) | Missense Mutation (SNP) | VAF 74/402 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV50141031; called by muse, mutect2
- TECR | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 130/421 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV53108382; called by muse, mutect2, varscan2
- TNNC2 | c.471G>T p.E157D | Missense Mutation (SNP) | VAF 179/512 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV65332691; called by muse, mutect2, varscan2
- TNRC6A | c.4285C>T p.Q1429* | Nonsense Mutation (SNP) | VAF 73/212 reads (34%) | catalogued as COSV59364998; called by muse, mutect2, varscan2
- TP53 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 52/94 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs750600586, CM123559, COSV52661339, COSV52708439, COSV53502932; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS52 | c.130del p.E44Sfs*26 | Frame Shift Del (DEL) | VAF 43/195 reads (22%) | catalogued as COSV71403507; called by mutect2*, pindel, varscan2*
- ZFP42 | c.598A>T p.R200W | Missense Mutation (SNP) | VAF 81/171 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58817695; called by muse, mutect2, varscan2
- CGB7 | c.-6_15+2del | Splice Site (DEL) | VAF 51/245 reads (21%) | called by mutect2, pindel
- DGKD | c.1758_1781del p.T587_S594del (on ENST00000264057 / NM_152879.3; = p.T543_S550del on NM_003648.3 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 73/186 reads (39%) | called by mutect2, pindel, varscan2
- LRRC10 | c.85_99del p.P29_M33del | In Frame Del (DEL) | VAF 62/258 reads (24%) | called by mutect2, pindel, varscan2
- RAI1 | c.5709+2_5709+26del p.X1903_splice | Splice Site (DEL) | VAF 34/96 reads (35%) | called by mutect2, pindel, varscan2
- VPS52 | c.131del p.E44Gfs*26 | Frame Shift Del (DEL) | VAF 61/179 reads (34%) | called by mutect2, varscan2
- ARMCX6 | c.435G>C p.A145= | Silent (SNP) | VAF 35/62 reads (56%) | catalogued as COSV62680776; called by muse, mutect2, varscan2
- CUL7 | c.4173G>A p.V1391= | Silent (SNP) | VAF 168/505 reads (33%) | catalogued as rs1470495551, COSV54817985; called by muse, mutect2, varscan2
- GNG11 | c.150G>A p.E50= | Silent (SNP) | VAF 42/113 reads (37%) | catalogued as COSV50350328; called by muse, mutect2, varscan2
- IL17RE | c.699G>T p.L233= | Silent (SNP) | VAF 122/386 reads (32%) | catalogued as COSV55968614; called by muse, varscan2
- KCNQ3 | c.1827C>A p.S609= | Silent (SNP) | VAF 86/454 reads (19%) | catalogued as COSV66472164; called by muse, mutect2, varscan2
- KDELR3 | c.447T>A p.T149= | Silent (SNP) | VAF 154/433 reads (36%) | catalogued as COSV53247908; called by muse, mutect2, varscan2
- LSR | c.936C>T p.G312= (on ENST00000361790; = p.G293= on NM_015925.6) | Silent (SNP) | VAF 66/162 reads (41%) | catalogued as COSV55887244, COSV55887389; called by muse, mutect2, varscan2
- MVD | c.642C>T p.G214= | Silent (SNP) | VAF 34/120 reads (28%) | catalogued as COSV55368457; called by muse, mutect2, varscan2
- NEK10 | c.2553C>T p.A851= | Silent (SNP) | VAF 127/399 reads (32%) | catalogued as rs777599695, COSV55359345; called by muse, mutect2, varscan2
- OR9Q1 | c.234C>T p.V78= | Silent (SNP) | VAF 203/506 reads (40%) | catalogued as COSV59041157; called by muse, mutect2, varscan2
- SLC9A9 | c.1248C>T p.S416= | Silent (SNP) | VAF 121/357 reads (34%) | catalogued as COSV57229459; called by muse, mutect2, varscan2
- TMEM155 | c.234C>T p.S78= | Silent (SNP) | VAF 60/180 reads (33%) | catalogued as rs1172631369, COSV61795058; called by muse, mutect2, varscan2
- UNC13B | c.1746G>A p.Q582= | Silent (SNP) | VAF 119/217 reads (55%) | catalogued as rs1371777184, COSV65935255; called by muse, mutect2, varscan2
- ZNF264 | c.144G>C p.G48= | Silent (SNP) | VAF 78/157 reads (50%) | catalogued as COSV54042134; called by muse, mutect2, varscan2
- COL6A2 | c.2462-2655A>T | Intron (SNP) | VAF 65/229 reads (28%) | catalogued as COSV56006697; called by muse, mutect2, varscan2
